Surgical pathology report (de-identified scan), TCGA case TCGA-4K-AAAL, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Proteogenex, Inc., specimen TCGA-4K-AAAL-01A (Primary Tumor).

ICD-O-3

Seminoma NOS 9061/3

Site: @ Testis NOS C62.9

W 5/21/14

Age/Sex: years / M

Date:

Procedure: Right orchiectomy

Preoperative diagnosis: TUMOR OF THE RIGHT TESTIS

Postoperative diagnosis: SEE MICROSCOPIC DIAGNOSIS BELOW

Specimen(s): 1. RIGHT TESTIS

Diagnosis:

1. RIGHT TESTIS:

- Seminoma
- Tumor does not invade the tunica albuginea and the epididymis
- Intratubular germ cell neoplasia and vascular invasion are present
- Resection margin is free of tumor

Gross description:

1. RIGHT TESTIS:

Received fresh, is a right testis 5.0 x 4.0 x 3.0 cm in dimensions with a portion of the spermatic cord 9.0 cm in length. In the testis there is a well-circumscribed tumor 2.5 x 2.0 x 2.0 cm in dimensions with a lobulated grayish-pink cut surface. The remaining testis tissue is soft-elastic and pale-brown. The epididymis is 3.0 x 1.0 x 1.0 cm in dimensions, firm-elastic, granular and grayish-white.

W 1/10/14

1/8/14

Source: NCI Genomic Data Commons file 73b885a5-3320-46c8-b94a-ccfc2a6fee3a (TCGA-4K-AAAL.6D785E8C-5D8D-4E08-80B7-E57F22DC3C0C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).